Somatic mutation profile of tumor specimen TCGA-RC-A6M6-01A (aliquot TCGA-RC-A6M6-01A-11D-A32G-10) from TCGA case TCGA-RC-A6M6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 75.7 years (27,649 days).
Specimen TCGA-RC-A6M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6721f05-496c-4174-831a-599551ee50c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A6M6-10A (Blood Derived Normal), aliquot TCGA-RC-A6M6-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39a9f811-99bd-4b4a-912b-cdcd12c4fd7d

The open-access MAF lists 204 somatic variants for this specimen: 165 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 36, Frame Shift Del 12, Nonsense Mutation 8, Splice Site 5, Frame Shift Ins 4, In Frame Del 3, 3'UTR 2, Splice Region 2, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD1 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV99635373; called by muse, mutect2, varscan2
- ADGRG5 | c.1201A>T p.M401L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100446369; called by muse, mutect2, varscan2
- AGAP1 | c.2543A>G p.N848S (on ENST00000304032 / NM_001037131.3; = p.N795S on NM_014914.5) | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.931); catalogued as COSV100364502; called by muse, mutect2, varscan2
- AGO4 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.584); catalogued as COSV100942870; called by muse, mutect2, varscan2
- ANKIB1 | c.1665T>G p.H555Q | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99728720; called by muse, mutect2, varscan2
- ANKS1B | c.1934C>G p.P645R | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV101612649, COSV61346658; called by muse, mutect2, varscan2
- ANKS6 | c.2604C>G p.S868R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as COSV100782252; called by muse, mutect2, varscan2
- APBB2 | c.1516G>A p.D506N (on ENST00000295974 / NM_001166050.2; = p.D507N on NM_004307.2) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs1415819462, COSV99922758; called by muse, mutect2, varscan2
- APEX1 | c.838T>A p.W280R | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99164458; called by muse, mutect2, varscan2
- ASTN1 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56061582, COSV99921010; called by muse, mutect2, varscan2
- ATP8A2 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99681127; called by muse, mutect2, varscan2
- ATP9A | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV100124947; called by muse, mutect2
- B3GAT1 | c.805A>C p.S269R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100437818, COSV100438172; called by muse, mutect2, varscan2
- BCL11B | c.2206C>A p.P736T (on ENST00000357195 / NM_001282237.2; = p.P665T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100595358; called by muse, mutect2, varscan2
- BNIP3 | c.351T>A p.H117Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV100893185; called by muse, mutect2, varscan2
- C3 | c.4720del p.D1574Mfs*21 | Frame Shift Del (DEL) | VAF 26/55 reads (47%) | catalogued as COSV99836793; called by mutect2, pindel, varscan2
- CAST | c.1043A>G p.D348G (on ENST00000341926; = p.D431G on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100352296; called by muse, mutect2, varscan2
- CCDC146 | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99592406; called by muse, mutect2, varscan2
- CCDC191 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99878068; called by muse, mutect2, varscan2
- CCDC33 | c.536T>C p.M179T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100351135; called by muse, mutect2, varscan2
- CEACAM3 | c.373A>T p.I125L | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as COSV99704913; called by muse, mutect2, varscan2
- CFAP43 | c.2112T>A p.D704E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV99530557; called by muse, mutect2, varscan2
- CFTR | c.2504A>T p.D835V | Missense Mutation (SNP) | VAF 66/454 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99135016; called by muse, varscan2
- CLEC16A | c.236T>G p.V79G | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.356); catalogued as COSV101277828; called by muse, mutect2, varscan2
- CNGA4 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs759681883, COSV66005316; called by muse, mutect2, varscan2
- COL22A1 | c.3981C>A p.G1327= | Splice Region (SNP) | VAF 28/66 reads (42%) | catalogued as rs772387414, COSV57329751; called by muse, mutect2, varscan2
- CSF2RB | c.2304G>T p.E768D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99453559; called by muse, mutect2, varscan2
- CYP3A43 | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as rs751527297, COSV99733062; called by muse, mutect2, varscan2
- DBN1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747285882, COSV99445820; called by muse, mutect2, varscan2
- DEF6 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.138); catalogued as rs764573391, COSV100359238; called by muse, mutect2, varscan2
- DEFB114 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs533824519, COSV100435373, COSV59037974; called by muse, mutect2, varscan2
- DMBT1 | c.3478T>C p.C1160R (on ENST00000338354 / NM_001377530.1; = p.C661R on NM_004406.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100352586; called by muse, mutect2, varscan2
- DNAH17 | c.6124G>C p.A2042P | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV101101872; called by muse, mutect2, varscan2
- DOCK2 | c.726G>C p.M242I | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as COSV99911324; called by muse, mutect2, varscan2
- EIF4E1B | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100024618; called by muse, mutect2, varscan2
- EMP1 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 68/245 reads (28%) | catalogued as COSV99916906; called by muse, mutect2, varscan2
- ERCC3 | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 37/105 reads (35%) | catalogued as COSV99573197; called by muse, mutect2, varscan2
- ERN2 | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99891071; called by muse, mutect2, varscan2
- EXT1 | c.1903T>G p.S635A | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV100983820; called by muse, mutect2, varscan2
- FAM47A | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV60500513; called by muse, mutect2, varscan2
- FAT4 | c.7280G>A p.R2427K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1463847765, COSV100628021; called by muse, mutect2, varscan2
- FBXL5 | c.1936G>T p.D646Y | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100377800; called by muse, mutect2, varscan2
- FGFR2 | c.1223A>G p.D408G | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.066); catalogued as COSV100335814; called by muse, mutect2, varscan2
- FNIP1 | c.2620T>A p.C874S | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100330365; called by muse, mutect2, varscan2
- GPR15 | c.281C>A p.A94E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as rs1269440025, COSV52520920, COSV99423693; called by muse, mutect2, varscan2
- GTPBP1 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99323043; called by muse, mutect2, varscan2
- HLA-DMA | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100877664; called by muse, mutect2, varscan2
- IL12B | c.88+1G>A p.X30_splice | Splice Site (SNP) | VAF 29/103 reads (28%) | catalogued as COSV99180332; called by muse, mutect2, varscan2
- IRAK4 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101471811; called by muse, mutect2, varscan2
- IRAK4 | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101471808; called by muse, mutect2, varscan2
- IRX1 | c.200del p.A67Gfs*32 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as COSV57358212; called by mutect2, pindel, varscan2
- ISM1 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99339741; called by muse, mutect2, varscan2
- JKAMP | c.487G>T p.A163S (on ENST00000554271 / NM_001284201.1; = p.A149S on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99711505; called by muse, mutect2, varscan2
- KEAP1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as rs970670762, COSV99407577; called by muse, mutect2, varscan2
- KIF1B | c.3900T>A p.H1300Q (on ENST00000377086 / NM_001365952.1; = p.H1254Q on NM_015074.3) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99822939; called by muse, mutect2, varscan2
- KIF26B | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101313820, COSV68572523; called by muse, mutect2, varscan2
- KMT2C | c.2892del p.S965Vfs*66 | Frame Shift Del (DEL) | VAF 30/338 reads (9%) | catalogued as COSV51282607; called by mutect2, pindel
- KRT9 | c.1405G>T p.G469* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV99879115; called by muse, mutect2, varscan2
- LAMA3 | c.9127C>A p.R3043S (on ENST00000313654 / NM_198129.4; = p.R1434S on NM_000227.6) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs778826328, COSV99334386; called by muse, mutect2, varscan2
- LINGO2 | c.1117C>A p.L373M | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs181261791, COSV100430410; called by muse, mutect2, varscan2
- LRFN2 | c.1678T>A p.C560S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100599348; called by muse, mutect2, varscan2
- LRPPRC | c.2505-2A>T p.X835_splice | Splice Site (SNP) | VAF 44/105 reads (42%) | catalogued as rs1330743871, COSV99580302; called by muse, mutect2, varscan2
- LRRC4B | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV100975880; called by muse, mutect2, varscan2
- MAP3K19 | c.2153A>G p.Q718R | Missense Mutation (SNP) | VAF 112/280 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1354845316, COSV100208341; called by muse, varscan2
- MATN3 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs376404727; called by muse, mutect2, varscan2
- MMACHC | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 45/110 reads (41%) | catalogued as COSV101284460; called by muse, mutect2, varscan2
- MYH1 | c.1626G>A p.M542I | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs752844108, COSV99875410, COSV99876509; called by muse, mutect2, varscan2
- MYH8 | c.2528T>A p.L843H | Missense Mutation (SNP) | VAF 159/241 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101238345; called by muse, mutect2, varscan2
- MYO7A | c.6629G>T p.G2210V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs765073964, COSV100265184; called by muse, mutect2, varscan2
- NFATC2 | c.1760G>A p.S587N | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV101043876; called by muse, mutect2, varscan2
- NLRP3 | c.1478A>G p.Q493R | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs768582957, COSV100275677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR14A16 | c.378C>A p.H126Q | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as COSV100713738; called by muse, mutect2, varscan2
- OR14K1 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 112/139 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99314924; called by muse, mutect2, varscan2
- OR2T8 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1193875912, COSV100178177, COSV60664030; called by muse, mutect2, varscan2
- OR4Q3 | c.128A>C p.Y43S | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100056903, COSV59179603; called by muse, mutect2, varscan2
- OR4Q3 | c.796A>T p.I266F | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100056905; called by muse, mutect2
- OR51M1 | c.307A>T p.S103C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100150188; called by muse, mutect2, varscan2
- OR5L1 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100449994; called by muse, mutect2, varscan2
- OR5V1 | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101011187, COSV65829581; called by muse, mutect2, varscan2
- OR6K2 | c.931A>T p.I311L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100656749; called by muse, mutect2
- PALLD | c.2609C>A p.A870D (on ENST00000505667 / NM_001166108.2; = p.A853D on NM_016081.4) | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54990804; called by muse, mutect2, varscan2
- PCDHA8 | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1554139135, COSV100970577; called by muse, mutect2, varscan2
- PCDHB8 | c.676A>T p.T226S | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.159); catalogued as COSV99176563; called by muse, varscan2
- PCF11 | c.4619C>T p.A1540V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100018053; called by muse, mutect2, varscan2
- PDCD1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV100545350; called by muse, mutect2, varscan2
- PDCD11 | c.1145C>A p.A382D | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100874279; called by muse, mutect2, varscan2
- PDGFRA | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV99956203; called by muse, varscan2
- PDXK | c.825A>T p.K275N | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99376261; called by muse, mutect2, varscan2
- PGC | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as COSV100756943; called by muse, mutect2, varscan2
- PIGO | c.537T>G p.D179E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99956556; called by muse, mutect2, varscan2
- PIGQ | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs959172804, COSV99215918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1047G>T p.E349D | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100724318; called by muse, mutect2, varscan2
- PODXL2 | c.666T>A p.H222Q | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs981133722, COSV100686264; called by muse, mutect2, varscan2
- PRDM2 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs377508263; called by muse, mutect2
- PRKCE | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100077361; called by muse, mutect2, varscan2
- PRPF31 | c.456T>A p.N152K | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as COSV100319917; called by muse, mutect2, varscan2
- PTPRR | c.1611A>C p.Q537H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.551); catalogued as COSV99316913; called by muse, mutect2, varscan2
- PTX4 | c.586C>A p.P196T (on ENST00000447419 / NM_001328608.2; = p.P191T on NM_001013658.1) | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as COSV99560334; called by muse, mutect2, varscan2
- PYROXD1 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV99556444; called by muse, mutect2, varscan2
- RAB19 | c.273C>G p.H91Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV99325034; called by muse, mutect2, varscan2
- RABL6 | c.318_319insAG p.C107Sfs*9 | Frame Shift Ins (INS) | VAF 39/70 reads (56%) | catalogued as COSV100273118; called by mutect2, pindel, varscan2
- RCSD1 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100827612; called by muse, mutect2, varscan2
- RIMBP2 | c.621T>A p.D207E | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99898941; called by muse, mutect2, varscan2
- RIMBP3 | c.3212C>A p.T1071N | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.933); catalogued as rs563786718; called by muse, mutect2, varscan2
- RTTN | c.2861A>G p.D954G | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378036167, COSV99731767; called by muse, mutect2, varscan2
- SEMA3E | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100318020, COSV57079809; called by muse, mutect2, varscan2
- SEMA6D | c.3218A>G p.Y1073C (on ENST00000316364 / NM_153618.2; = p.Y1011C on NM_020858.2) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100316731; called by muse, mutect2, varscan2
- SIN3A | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1294780529, COSV100845098; called by muse, mutect2, varscan2
- SLC45A3 | c.1357C>A p.L453M | Missense Mutation (SNP) | VAF 58/71 reads (82%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV100901112; called by muse, mutect2, varscan2
- SLC4A3 | c.2083C>T p.H695Y | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV56091335, COSV99812675; called by muse, mutect2, varscan2
- SLC6A13 | c.977T>G p.F326C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100569858; called by muse, mutect2, varscan2
- SLC6A3 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.612); catalogued as COSV54369186, COSV99548072; called by muse, varscan2
- SPEG | c.6401G>T p.G2134V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100403947; called by muse, mutect2, varscan2
- SPEG | c.8732C>A p.P2911Q | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV100403950; called by muse, mutect2, varscan2
- SPIRE1 | c.1720G>A p.E574K (on ENST00000409402 / NM_001128626.2; = p.E560K on NM_020148.3) | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100563537; called by muse, mutect2, varscan2
- SPTAN1 | c.4108G>T p.D1370Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100823411; called by muse, mutect2, varscan2
- STAB1 | c.5109C>A p.F1703L | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as rs1400286228, COSV100401474, COSV58743539; called by muse, mutect2, varscan2
- STYXL2 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs369939829, COSV54808365; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2213C>A p.A738D | Missense Mutation (SNP) | VAF 93/119 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs1239507187; called by muse, mutect2, varscan2
- SYT17 | c.1060A>T p.S354C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100810657; called by muse, mutect2, varscan2
- TCTE1 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV101025368; called by muse, mutect2, varscan2
- TFEB | c.468+1G>A p.X156_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100026090; called by muse, mutect2, varscan2
- TG | c.4592C>G p.A1531G | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV99599977; called by muse, mutect2, varscan2
- TKTL2 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761348402, COSV99761268; called by muse, mutect2, varscan2
- TNFRSF11B | c.1187T>G p.V396G | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99816537; called by muse, mutect2, varscan2
- TP53 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV52675742, COSV52676695, COSV53059791; called by muse, varscan2
- TTN | c.48233T>A p.V16078E (on ENST00000591111; = p.V8654E on NM_003319.4) | Missense Mutation (SNP) | VAF 54/156 reads (35%) | PolyPhen benign (0); catalogued as COSV100603265; called by muse, mutect2, varscan2
- TTN | c.36303G>T p.K12101N (on ENST00000591111; = p.K4677N on NM_003319.4) | Missense Mutation (SNP) | VAF 52/140 reads (37%) | PolyPhen probably damaging (0.997); catalogued as COSV100603267; called by muse, mutect2, varscan2
- TUBB8 | c.168T>A p.G56= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100225997; called by muse, mutect2, varscan2
- UBD | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV100589565; called by muse, mutect2, varscan2
- USH1C | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV99139654; called by muse, mutect2, varscan2
- VPREB3 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV99963471; called by muse, mutect2, varscan2
- WT1 | c.1223C>G p.P408R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100187606; called by muse, mutect2, varscan2
- XIRP1 | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV100453502; called by muse, mutect2, varscan2
- XIRP2 | c.7573del p.Q2525Kfs*19 (on ENST00000628543; = p.Q2700Kfs*19 on NM_152381.6) | Frame Shift Del (DEL) | VAF 40/135 reads (30%) | catalogued as COSV99743376; called by mutect2, pindel, varscan2
- ZBTB48 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100039579; called by muse, mutect2, varscan2
- ZCWPW1 | c.1562C>G p.A521G | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.398); catalogued as COSV99546375; called by muse, mutect2
- ZMYM2 | c.3757A>G p.T1253A | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.23); catalogued as COSV101243618; called by muse, mutect2, varscan2
- ZNF250 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 38/530 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV99480769; called by muse, mutect2
- ZNF577 | c.402A>T p.R134S | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100030932; called by muse, varscan2
- ZNF577 | c.318A>T p.K106N | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV100030934; called by muse, varscan2
- ZNF667 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV99410215; called by muse, mutect2, varscan2
- ZNF98 | c.1487G>C p.G496A | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100757377, COSV63340613; called by muse, mutect2, varscan2
- ABCE1 | c.623del p.H208Pfs*2 | Frame Shift Del (DEL) | VAF 43/130 reads (33%) | called by mutect2, pindel, varscan2
- ANK1 | c.1361_1366del p.K454_L456delinsI | In Frame Del (DEL) | VAF 84/238 reads (35%) | called by mutect2, pindel, varscan2
- APC2 | c.5054_5056dup p.E1685_W1686ins* | Nonsense Mutation (INS) | VAF 21/31 reads (68%) | called by mutect2, pindel, varscan2
- BSN | c.3062_3067dup p.Q1021_Q1022dup | In Frame Ins (INS) | VAF 22/39 reads (56%) | called by mutect2, varscan2
- CRACDL | c.1024del p.A342Pfs*157 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- CYTIP | c.542del p.L181* | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | called by mutect2, pindel, varscan2
- DNAH7 | c.4331dup p.K1445Efs*13 | Frame Shift Ins (INS) | VAF 96/330 reads (29%) | called by pindel, varscan2
- EVPL | c.1352_1355dup p.P453Gfs*22 | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- HAP1 | c.1964A>C p.H655P (on ENST00000310778 / NM_001367460.1; = p.H603P on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPR | c.149del p.R50Pfs*20 | Frame Shift Del (DEL) | VAF 92/351 reads (26%) | called by mutect2, pindel, varscan2
- LHX1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMBR1 | c.310dup p.L104Pfs*70 | Frame Shift Ins (INS) | VAF 27/46 reads (59%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 238/1380 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASSF10 | c.629del p.C210Sfs*101 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- SENP2 | c.384del p.S128Rfs*8 | Frame Shift Del (DEL) | VAF 50/158 reads (32%) | called by mutect2, pindel, varscan2
- SH2B3 | c.927-10_929del p.X309_splice | Splice Site (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- SLC9A4 | c.1154_1180del p.F385_Q394delins* | Nonsense Mutation (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- SPEG | c.2467_2469del p.P823del | In Frame Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- TNK2 | c.609+2T>A p.X203_splice | Splice Site (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- TRIM39 | c.489_490del p.K164Afs*11 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- TUBGCP6 | c.5176_5186del p.L1726Gfs*101 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- XKR4 | c.1924_1926del p.E642del | In Frame Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- AADAT | c.666A>G p.K222= | Silent (SNP) | VAF 65/150 reads (43%) | catalogued as COSV100528595; called by muse, mutect2, varscan2
- ACACA | c.4767G>A p.R1589= | Silent (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- ACAP1 | c.2106G>A p.A702= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV99341531; called by muse, mutect2, varscan2
- ACVR2A | c.804A>G p.A268= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV99604276; called by muse, mutect2, varscan2
- ARID3B | c.312T>C p.D104= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV100654584; called by muse, mutect2, varscan2
- CELA2A | c.180G>T p.G60= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV100657522; called by muse, mutect2, varscan2
- CSNK1A1L | c.174G>C p.L58= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV101131086; called by muse, mutect2, varscan2
- CYP3A43 | c.588C>T p.L196= | Silent (SNP) | VAF 134/226 reads (59%) | catalogued as COSV99733063; called by muse, varscan2
- DAGLB | c.480G>A p.G160= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV51704513; called by muse, mutect2, varscan2
- EDNRB | c.1026G>C p.L342= (on ENST00000377211 / NM_001201397.1; = p.L252= on NM_000115.5) | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100526455; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.30T>A p.S10= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99141536; called by muse, mutect2, varscan2
- F2RL3 | c.861G>T p.V287= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs770801019, COSV99935205; called by muse, varscan2
- GAS7 | c.669G>T p.L223= (on ENST00000432992 / NM_201433.2; = p.L83= on NM_003644.3) | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV100095078; called by muse, mutect2, varscan2
- GSE1 | c.2388G>A p.L796= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1447093636, COSV99496338; called by muse, mutect2, varscan2
- HDAC4 | c.1050C>T p.S350= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100613071; called by muse, mutect2, varscan2
- HPDL | c.405C>T p.R135= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV100587986; called by muse, mutect2, varscan2
- ITGA8 | c.1173A>C p.A391= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100959072; called by muse, mutect2, varscan2
- LINGO2 | c.1116C>A p.T372= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV100430412; called by muse, mutect2, varscan2
- MATK | c.510C>T p.R170= (on ENST00000310132 / NM_139355.3; = p.R171= on NM_002378.4) | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as rs766711251, COSV100035956; called by muse, mutect2, varscan2
- MNDA | c.1032T>C p.N344= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as rs1411842518, COSV100933229; called by muse, mutect2, varscan2
- NPR1 | c.759C>T p.T253= | Silent (SNP) | VAF 76/91 reads (84%) | catalogued as COSV100903737; called by muse, mutect2, varscan2
- OR5T2 | c.594T>C p.H198= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as COSV100506884; called by muse, mutect2, varscan2
- OR6K2 | c.933A>T p.I311= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as rs754789734, COSV62744233; called by muse, mutect2
- PCARE | c.12A>G p.T4= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100527449; called by muse, mutect2
- PCNT | c.9000A>T p.T3000= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100855296; called by muse, mutect2, varscan2
- POF1B | c.1201T>C p.L401= | Silent (SNP) | VAF 66/84 reads (79%) | catalogued as COSV99426399; called by muse, mutect2, varscan2
- RIPK3 | c.672C>A p.T224= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV99353102; called by muse, mutect2, varscan2
- SHISA3 | c.147C>T p.D49= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1229186103, COSV100069816; called by muse, mutect2, varscan2
- SLITRK3 | c.363C>T p.F121= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV99578863; called by muse, mutect2, varscan2
- STAC3 | c.546C>T p.R182= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV100234539; called by muse, mutect2, varscan2
- TENM1 | c.5103G>A p.T1701= | Silent (SNP) | VAF 58/74 reads (78%) | catalogued as rs148101479, COSV100949581; called by muse, mutect2, varscan2
- TRUB2 | c.711G>A p.K237= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs765647021, COSV100867838; called by muse, mutect2, varscan2
- VAC14 | c.1395G>T p.V465= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99934416; called by muse, mutect2, varscan2
- ZMYM1 | c.285T>A p.I95= | Silent (SNP) | VAF 88/221 reads (40%) | catalogued as COSV100720938; called by muse, mutect2, varscan2
- ZNF670 | c.258G>A p.Q86= | Silent (SNP) | VAF 59/67 reads (88%) | catalogued as COSV100829213; called by muse, mutect2, varscan2
- ZNF862 | c.2049C>A p.I683= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99783394, COSV99783456; called by muse, mutect2, varscan2
- MAPK12 | c.314+313G>C | Intron (SNP) | VAF 14/56 reads (25%) | catalogued as rs1314811285, COSV99299224; called by muse, mutect2, varscan2
- XIRP2 | c.*7C>A | 3'UTR (SNP) | VAF 99/290 reads (34%) | catalogued as COSV99740961; called by muse, mutect2, varscan2
- ZWINT | c.*94C>G | 3'UTR (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100571496; called by muse, mutect2, varscan2
